Gene-level copy-number profile of tumor specimen TCGA-13-1489-01A from TCGA case TCGA-13-1489, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 70.5 years (25,768 days).
Specimen TCGA-13-1489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bd52755a-499d-40c7-9f23-7aec08e3e558.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1489-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80abbd11-3939-4657-9a2a-0cabccffacbc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 581; copy number 2: 26,820; copy number 3: 1,938; copy number 4: 20,877; copy number 5: 2,738; copy number 6: 4,161; copy number 7: 2,195; copy number 8: 337; copy number 9: 103; copy number 10: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1489-01A-01D-0472-01): tumor purity 0.88, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,374,201–49,691,523, 2 genes (within-gene range 0–2): AGBL4-IT1, AL390023.1.
- chr20:59,577,509–59,847,711, 1 gene (within-gene range 0–4): PHACTR3.
- chr20:59,852,667–59,852,728, 1 gene: RNU7-141P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,551 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:108,495,475–109,275,751, 30 genes, copy number 6 (within-gene range 4–6): AL392088.2, ST13P21, AL392088.1, FAM102B, HENMT1, AL160171.1, PRPF38B, FNDC7, AL591719.2, STXBP3, AL591719.1, AKNAD1, SPATA42, GPSM2, CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5, TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1, SARS1, CELSR2.
- chr1:147,019,656–165,356,715, 782 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:237,862,175–248,919,946, 270 genes, copy number 6–10 (broad region; genes not listed).
- chr2:34,799,850–35,185,689, 1 gene, copy number 6 (within-gene range 4–6): AC012593.1.
- chr2:34,998,273–35,219,604, 2 genes, copy number 6: AC019064.1, SMIM7P1.
- chr2:117,139,715–118,110,997, 14 genes, copy number 6 (within-gene range 4–6): RNU7-190P, AC092170.1, AC064856.1, AC009312.1, DDX18, AC009404.1, HTR5BP, CCDC93, AC009303.1, AC009303.2, AC009303.3, AC009303.4, RN7SL111P, INSIG2.
- chr2:176,077,472–176,930,090, 34 genes, copy number 6: EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67, LINC01117, AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P.
- chr2:178,723,457–242,160,153, 1,125 genes, copy number 6 (broad region; genes not listed).
- chr3:115,100,423–115,721,490, 7 genes, copy number 6: ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3, GAP43, AC092468.1.
- chr3:115,837,870–115,838,159, 1 gene, copy number 6: RN7SL815P.
- chr3:140,449,435–198,222,513, 1,008 genes, copy number 7–10 (broad region; genes not listed).
- chr5:154,685,776–181,342,213, 518 genes, copy number 5–6 (broad region; genes not listed).
- chr6:134,074,123–144,853,034, 173 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr6:145,296,545–145,887,430, 11 genes, copy number 5: AL023283.1, EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT.
- chr7:6,710,128–6,753,862, 1 gene, copy number 6 (within-gene range 4–6): PMS2CL.
- chr7:6,754,109–26,647,305, 265 genes, copy number 6–8 (broad region; genes not listed).
- chr7:57,770,619–63,790,098, 56 genes, copy number 5–9: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1, AC079355.1, CICP24, AC079355.2.
- chr7:74,231,499–86,864,884, 178 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:94,801,514–97,872,542, 43 genes, copy number 6 (within-gene range 4–6): RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1, RN7SKP104, TAC1, ASNS.
- chr7:97,870,167–97,870,289, 1 gene, copy number 6: AC005326.1.
- chr7:140,719,327–159,233,377, 478 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:103,500,696–104,256,094, 1 gene, copy number 6 (within-gene range 4–6): RIMS2.
- chr8:104,330,324–109,121,565, 51 genes, copy number 6 (within-gene range 4–6): DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR.
- chr9:93,576,584–94,109,856, 8 genes, copy number 6 (within-gene range 2–6): PHF2, MIR548AU, AL442224.1, MIR4291, BARX1, BARX1-DT, PTPDC1, CYCSP24.
- chr10:114,690,143–133,761,125, 328 genes, copy number 5–7 (broad region; genes not listed).
- chr11:64,778,954–122,027,667, 1,380 genes, copy number 5–9 (broad region; genes not listed).
- chr11:122,099,757–122,146,593, 3 genes, copy number 7: MIR125B1, BLID, MIRLET7A2.
- chr12:14,169,746–32,646,050, 323 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:57,391,171–67,267,706, 75 genes, copy number 5–9 (broad region; genes not listed).
- chr14:74,614,693–77,616,637, 98 genes, copy number 6 (broad region; genes not listed).
- chr15:61,638,928–101,933,350, 1,053 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr17:51,630,313–83,095,122, 918 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:87,250–10,673,999, 243 genes, copy number 5 (broad region; genes not listed).
- chr20:47,630,266–50,479,991, 72 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 485. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
